Somatic mutation profile of tumor specimen MP2PRT-PAPKRX-TMP1-A (aliquot MP2PRT-PAPKRX-TMP1-A-1-0-D-A83A-36) from MP2PRT case MP2PRT-PAPKRX, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute lymphoblastic leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 3.0 years (1,109 days).
Specimen MP2PRT-PAPKRX-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 546ad6cd-5ddb-495f-8e72-0d85a78c2a1d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAPKRX-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAPKRX-NB1-A-1-0-D-A83A-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/559ff246-7bc1-474b-bca5-0cb36ab82902

The open-access MAF lists 26 somatic variants for this specimen: 19 protein-altering or splice-affecting, 7 silent.
By variant classification: Missense Mutation 17, Silent 7, Nonsense Mutation 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KMT2D | c.14710C>T p.R4904* | Nonsense Mutation (SNP) | VAF 148/367 reads (40%) | catalogued as rs398123721, CM105476, COSV56414273; ClinVar: pathogenic; called by muse, mutect2, varscan2
- NRAS | c.38G>A p.G13D | Missense Mutation (SNP) | VAF 37/272 reads (14%) | hotspot (GDC flag); SIFT deleterious (0.05); PolyPhen benign (0.323); catalogued as rs121434596, CM071907, COSV54736416, COSV54736480, COSV54736793; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- PTPN11 | c.922A>G p.N308D | Missense Mutation (SNP) | VAF 64/206 reads (31%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen benign (0.134); catalogued as rs28933386, CM013422, COSV61006575; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ACBD5 | c.1300C>T p.R434C (on ENST00000375888 / NM_001352568.1; = p.R425C on NM_145698.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 38/656 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs779982287; called by muse, mutect2
- BMP6 | c.768C>A p.F256L | Missense Mutation (SNP) | VAF 30/494 reads (6%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.967); catalogued as rs771409026, COSV99306709; called by muse, mutect2
- BRWD1 | c.1177C>T p.R393W | Missense Mutation (SNP) | VAF 46/369 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs999989755, COSV60896807; called by muse, mutect2, varscan2
- COL21A1 | c.451G>A p.V151I | Missense Mutation (SNP) | VAF 65/432 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs765241387, COSV99777852; called by muse, mutect2, varscan2
- CYP11B1 | c.1022G>A p.R341H | Missense Mutation (SNP) | VAF 204/461 reads (44%) | SIFT tolerated (0.1); PolyPhen benign (0.098); catalogued as rs1304494959, COSV52825464, COSV52828663; called by muse, mutect2, varscan2
- MYH4 | c.5146C>T p.R1716C | Missense Mutation (SNP) | VAF 41/304 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.625); catalogued as rs201824445; called by muse, mutect2, varscan2
- SLC2A6 | c.866C>T p.T289M | Missense Mutation (SNP) | VAF 51/397 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.184); catalogued as rs782462512; called by muse, mutect2, varscan2
- SLC34A2 | c.1880G>A p.R627H | Missense Mutation (SNP) | VAF 106/641 reads (17%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.732); catalogued as rs974734046; called by muse, varscan2
- TBX3 | c.1724C>T p.A575V (on ENST00000257566 / NM_016569.4; = p.A555V on NM_005996.4) | Missense Mutation (SNP) | VAF 52/503 reads (10%) | SIFT tolerated (0.1); PolyPhen benign (0.147); catalogued as rs1263505115; called by muse, mutect2, varscan2
- TSHR | c.1826G>A p.R609Q | Missense Mutation (SNP) | VAF 164/561 reads (29%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.776); catalogued as rs139352934, CM120225; called by muse, mutect2, varscan2
- CLPS | c.44C>T p.A15V | Missense Mutation (SNP) | VAF 90/527 reads (17%) | SIFT tolerated (0.19); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- KMT2D | c.1708T>G p.S570A | Missense Mutation (SNP) | VAF 134/455 reads (29%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- NALCN | c.4357T>C p.F1453L | Missense Mutation (SNP) | VAF 48/214 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- PLXNB3 | c.1632C>A p.V544= | Splice Region (SNP) | VAF 69/435 reads (16%) | called by muse, mutect2, varscan2
- RSL24D1 | c.140G>C p.R47P | Missense Mutation (SNP) | VAF 49/303 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.831); called by muse, mutect2, varscan2
- TMEM271 | c.498C>A p.S166R | Missense Mutation (SNP) | VAF 120/575 reads (21%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0); called by muse, mutect2, varscan2
- ADAMTS5 | c.999C>T p.N333= | Silent (SNP) | VAF 46/648 reads (7%) | called by muse, mutect2
- ATXN1 | c.1203T>A p.T401= | Silent (SNP) | VAF 152/463 reads (33%) | called by muse, mutect2, varscan2
- KIF5C | c.2784C>T p.P928= | Silent (SNP) | VAF 73/329 reads (22%) | catalogued as rs1000086773; called by muse, mutect2, varscan2
- OTOP1 | c.24C>T p.P8= | Silent (SNP) | VAF 56/658 reads (9%) | called by muse, mutect2
- PCDHGA3 | c.2091G>A p.V697= | Silent (SNP) | VAF 68/624 reads (11%) | catalogued as COSV99538199; called by muse, varscan2
- RBMXL3 | c.2427C>T p.N809= | Silent (SNP) | VAF 124/782 reads (16%) | catalogued as rs781842556; called by muse, varscan2
- SARM1 | c.615C>T p.A205= | Silent (SNP) | VAF 29/580 reads (5%) | catalogued as rs782735222; called by muse, mutect2
